Somatic mutation profile of tumor specimen TCGA-DM-A1DB-01A (aliquot TCGA-DM-A1DB-01A-11D-A152-10) from TCGA case TCGA-DM-A1DB, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.1 years (24,888 days).
Specimen TCGA-DM-A1DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e47dbc51-af85-4deb-b4b8-b8264c9ade82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1DB-10A (Blood Derived Normal), aliquot TCGA-DM-A1DB-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/973a4123-b087-4c6c-89ed-ff04050d3483

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 13, Nonsense Mutation 4, Intron 1, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 138/184 reads (75%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- L1CAM | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 75/256 reads (29%) | catalogued as rs1557091773, CM970857, COSV62828861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-6_1751del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 48/81 reads (59%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/51 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as rs368457541; called by muse, mutect2, varscan2
- ADAMTS17 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs201896149; ClinVar: likely benign; called by muse, mutect2, varscan2
- AKR1B10 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.096); catalogued as COSV62056021; called by muse, mutect2, varscan2
- AP3D1 | c.2329G>A p.V777I | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs775564429, COSV61430801; called by muse, mutect2, varscan2
- ASTN2 | c.1714C>A p.L572M (on ENST00000313400 / NM_001365069.1; = p.L521M on NM_014010.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57771522; called by muse, mutect2, varscan2
- AXIN2 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs751229839, COSV100195894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR3 | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as rs1290029544, COSV50911521, COSV51051760; called by muse, mutect2, varscan2
- CHD7 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71112802; called by muse, mutect2, varscan2
- CRISP1 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV59994506, COSV59994908; called by muse, mutect2, varscan2
- CXXC1 | c.1832A>G p.K611R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); catalogued as COSV53275766; called by muse, mutect2, varscan2
- EDEM3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV58922307, COSV58926298; called by muse, mutect2, varscan2
- FANCG | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62721376; called by muse, mutect2, varscan2
- FLG | c.10450A>C p.S3484R | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64244143; called by muse, varscan2
- GNB2 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV51944456; called by muse, mutect2, varscan2
- GRIN2A | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.045); catalogued as COSV58027984; called by muse, mutect2, varscan2
- H3C2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- H4C9 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs200159567, COSV62890071; called by muse, mutect2, varscan2
- ITPRID2 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV57474295; called by muse, mutect2, varscan2
- KPRP | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs767386948, COSV64222306; called by muse, mutect2, varscan2
- MC3R | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1481948431, COSV54763393; called by muse, mutect2, varscan2
- MTMR11 | c.1909C>T p.R637C (on ENST00000439741 / NM_001145862.2; = p.R565C on NM_181873.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs371578546; called by muse, mutect2, varscan2
- NKX6-2 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV63973897; called by muse, mutect2, varscan2
- NTN4 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as rs376168277, COSV59220679; called by muse, mutect2, varscan2
- NXF3 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 190/204 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV67704464; called by muse, mutect2, varscan2
- OR2T33 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58816590; called by muse, mutect2, varscan2
- PCDHB13 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 38/68 reads (56%) | catalogued as rs782055332, COSV99507212; called by muse, mutect2, varscan2
- PCDHB8 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 119/210 reads (57%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.288); catalogued as COSV50792671; called by muse, mutect2, varscan2
- PDE3A | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100762043, COSV62974825, COSV62977746; called by muse, mutect2, varscan2
- PKHD1 | c.7567A>G p.I2523V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs146962673, COSV61886813; ClinVar: uncertain significance; called by muse, mutect2
- PLCB1 | c.1584G>T p.G528= | Splice Region (SNP) | VAF 12/46 reads (26%) | catalogued as COSV62059786; called by muse, varscan2
- PLPPR1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as COSV66455366; called by muse, mutect2, varscan2
- RNF126 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs756568943, COSV99443032; called by muse, mutect2, varscan2
- RUFY1 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 122/164 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1057175407, COSV60162031; called by muse, mutect2, varscan2
- SLC36A4 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100419428, COSV58396947; called by muse, mutect2, varscan2
- SLFNL1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs762696363, COSV57235076; called by muse, mutect2, varscan2
- SMYD2 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs887231491, COSV65291389; called by muse, mutect2, varscan2
- SYNE1 | c.3908A>G p.E1303G (on ENST00000367255 / NM_182961.4; = p.E1310G on NM_033071.3) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99562906; called by muse, mutect2, varscan2
- TAS2R46 | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 93/322 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV101114617, COSV67859255; called by muse, mutect2, varscan2
- TTN | c.81029T>C p.L27010P (on ENST00000591111; = p.L19586P on NM_003319.4) | Missense Mutation (SNP) | VAF 77/201 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV60194315; called by muse, mutect2, varscan2
- TTPAL | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52829392; called by muse, mutect2, varscan2
- UNC45B | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs753397675, COSV52098268; called by muse, mutect2, varscan2
- UVSSA | c.2127C>G p.N709K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV66230378; called by muse, mutect2, varscan2
- ZFAT | c.2978C>A p.P993H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64742172; called by muse, mutect2, varscan2
- ZNF211 | c.590A>G p.N197S (on ENST00000347302 / NM_198855.4; = p.N210S on NM_006385.5) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99560256; called by muse, mutect2, varscan2
- COL5A2 | c.1192_1205delinsTCA p.E398Sfs*5 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2*
- AGBL1 | c.2886G>A p.E962= | Silent (SNP) | VAF 52/94 reads (55%) | catalogued as COSV66865227, COSV66869636; called by muse, mutect2, varscan2
- CDH23 | c.7176C>T p.I2392= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs375991880; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHAD | c.210G>A p.S70= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs1434340311, COSV51973417; called by muse, mutect2, varscan2
- FAT3 | c.8109G>A p.T2703= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as rs779853971, COSV53124233; called by muse, mutect2, varscan2
- KCNV1 | c.255C>T p.P85= | Silent (SNP) | VAF 57/92 reads (62%) | catalogued as COSV52087463; called by muse, mutect2, varscan2
- KEAP1 | c.24C>T p.S8= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs758239745, COSV50262074, COSV50271445; called by muse, mutect2, varscan2
- MYH8 | c.3186C>G p.L1062= | Silent (SNP) | VAF 163/237 reads (69%) | catalogued as COSV67968954; called by muse, mutect2, varscan2
- NAV2 | c.3456C>T p.A1152= (on ENST00000396087 / NM_001244963.2; = p.A1129= on NM_145117.5) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs769380660, COSV60662047; called by muse, mutect2, varscan2
- NLRP6 | c.375C>T p.H125= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as COSV56461019; called by muse, mutect2, varscan2
- PER1 | c.462G>A p.R154= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100424379; called by muse, mutect2
- RNF145 | c.1473C>T p.F491= (on ENST00000424310 / NM_001199383.2; = p.F519= on NM_144726.2) | Silent (SNP) | VAF 62/87 reads (71%) | catalogued as rs374534238; called by muse, mutect2, varscan2
- SLC2A6 | c.510G>A p.G170= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV64143110; called by muse, mutect2, varscan2
- ZNF813 | c.1596T>C p.F532= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs1368139982, COSV67177353; called by muse, mutect2, varscan2
- TTN | c.34265-4491G>A | Intron (SNP) | VAF 183/448 reads (41%) | catalogued as rs759305693, COSV59861803; called by muse, mutect2, varscan2
